Somatic mutation profile of tumor specimen MP2PRT-PARMFW-TMP1-A (aliquot MP2PRT-PARMFW-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARMFW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,089 days).
Specimen MP2PRT-PARMFW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a3f6ed-db56-427c-9350-bdbb05a14c2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMFW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMFW-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/420dbebe-bb0a-4656-9c5f-ec5db82fd61b

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCP | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 231/503 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs375491885; called by muse, mutect2
- KRT26 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 123/303 reads (41%) | catalogued as rs376841856; called by muse, mutect2, varscan2
- MED13 | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67267659; called by muse, mutect2
- ATP1A2 | c.832G>T p.G278W | Missense Mutation (SNP) | VAF 34/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDC73 | c.147_167delinsG p.Q50Ifs*9 | Frame Shift Del (DEL) | VAF 73/323 reads (23%) | called by pindel, varscan2*
- DAO | c.960G>T p.W320C | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DSP | c.4586A>G p.K1529R | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- GIGYF2 | c.2827delinsCCAATGAC p.T943Pfs*8 | Frame Shift Ins (INS) | VAF 135/404 reads (33%) | called by pindel, varscan2*
- GPR152 | c.1106A>C p.D369A | Missense Mutation (SNP) | VAF 52/650 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2
- IGHV3-7 | chr14:106062143 ACTGTGTCTCTC>TTTACGGCG | Missense Mutation (DEL) | VAF 106/158 reads (67%) | called by pindel, varscan2*
- IGKV1OR2-108 | c.351_353delinsCCTCCCCA p.*118Lfs*? | Frame Shift Ins (INS) | VAF 19/70 reads (27%) | called by pindel, varscan2*
- RAB5C | c.368C>G p.A123G | Missense Mutation (SNP) | VAF 49/391 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.983); called by muse, mutect2
- STXBP2 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 201/456 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- TRPC3 | c.2007C>A p.F669L (on ENST00000379645 / NM_001366479.2; = p.F596L on NM_003305.2) | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2
- UBXN2B | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.315); called by muse, mutect2
- CELSR3 | c.9663G>A p.P3221= | Silent (SNP) | VAF 264/609 reads (43%) | catalogued as rs532815297; called by muse, mutect2, varscan2
- CT47B1 | c.414C>T p.N138= | Silent (SNP) | VAF 232/262 reads (89%) | catalogued as rs753044690, COSV64890468, COSV64891176; called by muse, mutect2, varscan2
- GPR152 | c.1107T>C p.D369= | Silent (SNP) | VAF 54/651 reads (8%) | called by muse, mutect2
